Somatic mutation profile of tumor specimen TCGA-AC-A2FF-01A (aliquot TCGA-AC-A2FF-01A-11D-A17D-09) from TCGA case TCGA-AC-A2FF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-AC-A2FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3c1fa95-d593-4391-aff7-5e3bb6b797d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A2FF-11A (Solid Tissue Normal), aliquot TCGA-AC-A2FF-11A-13D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cde69f4-e022-47b0-8d91-2a7b8e03805f

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2
- AKT3 | c.1118C>G p.A373G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV55611651; called by muse, mutect2, varscan2
- GRM1 | c.2013C>A p.C671* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV51120557; called by muse, mutect2, varscan2
- IL9 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50853545, COSV99192430; called by muse, mutect2
- PTEN | c.593T>A p.M198K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1554900635, CD110183, CM124223, COSV64288507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK39 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63595683; called by muse, mutect2, varscan2
- ZNF223 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV71571818; called by muse, mutect2, varscan2
- CDH1 | c.258_259del p.R87Afs*6 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2147_2148dup p.L717Sfs*9 | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
